Gene-level copy-number profile of tumor specimen HCM-SANG-1082-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-1082-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1082-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 73d7f9d5-4fee-4de1-8b61-2ce115bce910.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1082-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/a4499ba9-9d99-44b1-9b41-b64fc03e41fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 20,766; copy number 2: 36,179; copy number 3: 1,228; copy number 4: 35; copy number 5: 50; copy number 6: 30; copy number 7: 36; copy number 8: 53; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:64,784,918–64,844,653, 3 genes: MAP4K2, MEN1, CDC42BPG.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 171 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–195,411, 8 genes, copy number 7: AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr11:67,317,871–67,398,410, 3 genes, copy number 5 (within-gene range 4–7): RAD9A, POLD4, AP003419.1.
- chr11:67,362,414–70,436,584, 117 genes, copy number 5–9 (broad region; genes not listed).
- chr11:72,239,077–72,674,591, 18 genes, copy number 5 (within-gene range 1–5): PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P.
- chr11:72,685,069–72,793,599, 1 gene, copy number 5 (within-gene range 4–5): ARAP1.
- chr11:72,689,650–72,695,821, 1 gene, copy number 5 (within-gene range 4–5): AP003065.1.
- chr11:72,754,729–73,598,189, 23 genes, copy number 5: STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38.

Autosomal genes at a single copy (total copy number 1): 18,422. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
